Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A7ER, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A7ER-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

Clinical Diagnosis & History:
Right lower lobe FNA (+) synovial sarcoma.

Specimens Submitted:
1: SP: Level seven mediastinal lymph nodes
2: SP: Right lower lobe lung and tumor

DIAGNOSIS:

1. LYMPH NODE, LEVEL VII MEDIASTINAL; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
2. LUNG, RIGHT LOWER LOBE; LOBECTOMY:
- SYNOVIAL SARCOMA, MONOPHASIC SUB TYPE.
- TUMOR IS FRAGMENTED MEASURING 20 CM IN AGGREGATE.
- MITOTIC RATE IS ABOUT 5 MITOSIS/10 HIGH POWER FIELDS.
- TUMOR SHOWS ABOUT 40% NECROSIS.
- TUMOR EXTENSIVELY INVOLVES THE VISCERAL AND PARIETAL PLEURA AND INVADERS FOCALLY INTO THE LUNG PARENCHYMA.
- THE BRONCHIAL, VASCULAR AND PARENCHYMAL MARGINS ARE FREE OF TUMOR.
- TWO BENIGN LYMPH NODES (0/2).
- THE PREVIOUS BIOPSY HAS BEEN REVIEWED.
- IMMUNOHISTOCHEMICAL STAINS SHOW POSITIVE STAINING FOR VIMENTIN AND CYTOKERATIN CAM 5.2 (RARE CELLS) AND NEGATIVE STAINING FOR CD34. THESE FINDINGS SUPPORT THE ABOVE DIAGNOSIS. TLE1 STAIN IS NEGATIVE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

** Continued on next page **

ICD-O-3
Sarcoma, synovial monophasic
fibrous 9041/3
Site ^{C64F} Chest NOS C49.3
^{path}
R Lung, lower lobe C34.3
90426/13

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 3

1). The specimen is received in formalin, labeled "Level 7 mediastinal lymph node" and consists of a single anthracotic lymph node measuring 1.4 x 0.8 x 0.4 cm. The lymph node is bisected and entirely submitted.

Summary of sections:

LN- lymph node

2) The specimen is received fresh and is labeled, "right lower lobe lung and tumor". It consists of a 17.2 x 4.6 x 3.9 cm lung lobe with attached bronchus and blood vessels straddled by multiple staple lines, which weighs 191 gm. The attached bronchus measures 1.9 x 0.3 cm. Adherent to the lateral aspect of the lobe is parietal pleura with fragments of friable tumor. The visceral pleura shows fibrinous exudates. Accompanying the specimen is an aggregate of tan friable tumor that measures 20.0 x 18.0 x 2.8 cm. Cut surfaces of the lung show no masses within the lung parenchyma. Peribronchial anthracotic lymph nodes are identified and submitted. The uninvolved lung parenchyma shows congested areas. Representative sections are submitted. TPS is submitted. Photographs are taken.

Summary of sections:

BM -- bronchial margin.
VM -- vascular margin.
SM -- staple edge.
TP -- tumor with pleura.
ST -- separate tumor fragments, representative sections
R - non-tumor lung, random
LN -- lymph nodes

Summary of Sections:

Part 1: SP: Level seven mediastinal lymph nodes

Block	Sect.	Site	PCs
1		ln	1

Part 2: SP: Right lower lobe lung and tumor

Block	Sect.	Site	PCs
1		BM	1
1		LN	2
4		R	4
1		SM	2
10		ST	20
4		TP	4
1		VM	2

** Continued on next page **

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

[REDACTED]

[REDACTED]

Page 3 of 3

** End of Report **

[page 4 of 5]
DEPARTMENTAL CONSULT

Patient: [REDACTED]

....

Clinical Diagnosis & History:
Sarcoma

Specimens Submitted:

- 1: LUNG, RIGHT LOWER LOBE, BRONCHIAL BIOPSY [REDACTED]; 3 SLIDES)
2: LUNG, RIGHT LOWER LOBE, MASS OF LESION, BIOPSY [REDACTED]; 1 SLIDE)

DIAGNOSIS:

1. LUNG, RIGHT LOWER LOBE, BRONCHIAL BIOPSY [REDACTED] 3 SLIDES):
- UNREMARKABLE BRONCHIAL MUCOSA.
- NO TUMOR SEEN.
2. LUNG, RIGHT LOWER LOBE, MASS OF LESION, BIOPSY [REDACTED]; 1 SLIDE):
- SYNOVIAL SARCOMA, SEE NOTE.

NOTE: PER REPORT, MOLECULAR ANALYSIS WAS PERFORMED REVEALING SYT-SSX1 AND SSX2 TRANSLOCATIONS. THIS IS CONSISTENT WITH SYNOVIAL SARCOMA.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Summary of Sections:

Part 1: LUNG, RIGHT LOWER LOBE, BRONCHIAL BIOPSY [REDACTED] 3 SLIDES)

** Continued on next page **

[page 5 of 5]
DEPARTMENTAL CONSULT

----- Page 2 of 2
Part 2: LUNG, RIGHT LOWER LOBE, MASS OF LESION, BIOPSY ([REDACTED]
[REDACTED] 1 SLIDE)

** End of Report **

Source: NCI Genomic Data Commons file 3658f9aa-44f9-47d4-99a7-eb1849ce1e88 (TCGA-DX-A7ER.545247A0-699B-43A1-824A-C6E2EB1B7565.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).